Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8A8, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8A8-01A (Primary Tumor).

[page 1 of 3]
Panel: Surgical Pathology Final Report

Date:

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-In progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
Surgical Pathology Final Report Collection d/t:	[REDACTED] F	[REDACTED]	[REDACTED]			
Obs d/t:						
Ordered by:						

Surgical Pathology Report

ICD-O-3
Carcinoma, embryonal NOS 9070/3
Tumor germ cell mixed 9055/3
Site: R Testis NOS C62.9
7/25/30/14

Final Diagnosis

1. Testis, 83.7g, right, radical orchiectomy:

A. Malignant mixed germ cell tumor, with predominantly embryonal cell carcinoma

(approximately 95%), mature teratoma (approximately 5%), and rare yolk sac component, see note.

B. Intratubular germ cell neoplasia present.

C. The tumor is confined to the testis. There is no involvement of the tunica albuginea or vaginalis. The rete testis and the epididymis are not involved. No lymphovascular invasion identified.

D. Spermatic cord and spermatic cord margin, free of tumor.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Note

Immunohistochemical stains performed with adequate controls demonstrate extensive positivity for CD30 in the embryonal carcinoma and rare foci of membranous AFP-positivity in the region with yolk sac tumor. highlights the intratubular germ cell neoplasia. Rare HCG positive cells noted, however no cyto, and syncytiotrophoblastic cells are present in the region of hemorrhage. See disclaimer

Pathologist(s)

[page 2 of 3]
Microscopic Description

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or RUO reagents were developed and their performance characteristics were validated for diagnostic use by the

laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Gross Description

The case is received in one container, labeled with the patient's name and medical record number.

Specimen 1 is received fresh designated "right testicle" and consists of a radical orchiectomy specimen with a testicle measuring 7 x 4.3 x 4.2 cm, and a spermatic cord measuring 8.5 cm in length and 2.5 cm in average diameter. The specimen weighs 83.7 g. The spermatic cord margin is shaved and submitted as 1A. The specimen is inked black in entirety. The testicle is bisected through the long axis of the testicle towards the hilum, revealing two separate masses. The first measures 3.9 x 3.7 x 3.2 cm, and the second measures 2.7 x 2.1 x 1.9 cm. These masses are separated by a thin, 2 mm potential capsule. Neither one of these masses invade the tunica albuginea. Neither one of these masses grossly invades the epididymis or extend beyond the testicle. The larger mass is white yellow, and potentially hemorrhagic. The smaller mass is yellow-brown with potential necrosis. Rep. sections are as follows:

1A is the spermatic cord shave margin.

1B is a representative section of the larger tumor.

1C is the smaller tumor in relationship to potential tumor involving the rete testis.

1D through 1F are representative sections of larger tumor, with 1D being a representative section in relationship to tunica vaginalis.

1G and 1H are representative sections of smaller tumor.

1I is a representative section of uninvolved testis and epididymis.

1J is separate sections of uninvolved testis and epididymis.

1K, 1L, and 1M are representative section of the proximal, mid, and distal portions of the epididymis, respectively.

[page 3 of 3]
SUMMARY OF SECTIONS: 13, multiple, representative

Dictated by:

Clinical Information

year-old male with right testicular mass
Pre-Operative Diagnosis: Not specified
Post-Operative Diagnosis: Not specified
Operation: Right radical orchiectomy
Specific questions to be answered: No questions.

Specimen:

1 Right Testicle

*** End of report ***

Pw TSS, 95% embryonal
5% mature teratoma

Source: NCI Genomic Data Commons file 05c47af5-da4c-4dfb-a50d-607e6523e574 (TCGA-VF-A8A8.9C548C5D-77A7-47EE-BCE5-76EF2E7197EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).